Gene-level copy-number profile of tumor specimen BLGSP-71-06-00002-01D from CGCI case BLGSP-71-06-00002, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: female; Vital status: Dead; Primary diagnosis: Burkitt-like lymphoma; Tissue or organ of origin: Hematopoietic system, NOS.
Specimen BLGSP-71-06-00002-01D: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 48949eae-d946-4645-b1fa-8e2a1a355262.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-06-00002-99A (granulocytes); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,244 have no estimate.
https://portal.gdc.cancer.gov/files/abba80cb-6283-4db4-987f-3fc71e512ffc

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 209; copy number 2: 435; copy number 3: 141; copy number 4: 53,369; copy number 5: 3,952; copy number 6: 228; copy number 7: 9; copy number 8: 2; copy number 9: 4; copy number 10: 3; copy number 11: 3; copy number 12: 2; copy number 13: 1; copy number 14: 1; copy number 15: 1; copy number 16: 1; copy number 19: 5; copy number 25: 8; copy number 33: 5.

Homozygous deletions (total copy number 0; autosomes only): 209 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–89,245,596, 41 genes (within-gene range 0–6): MALLP2, AC244205.1, MIR4436A, IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30.
- chr9:21,802,636–22,128,103, 14 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr14:105,672,308–106,481,706, 115 genes (within-gene range 0–4) (broad region; genes not listed).
- chr14:106,531,141–106,538,344, 2 genes (within-gene range 0–3): IGHVIII-47-1, IGHV3-48.
- chr22:22,697,789–22,901,437, 37 genes: IGLV2-23, IGLVVI-22-1, IGLV3-22, IGLV3-21, IGLVI-20, IGLV3-19, AC244250.3, IGLV2-18, IGLV3-17, IGLV3-16, IGLV3-15, IGLV2-14, IGLV3-13, IGLV3-12, AC244157.1, AC244157.2, IGLV2-11, AC245028.3, IGLV3-10, AC245028.1, IGLV3-9, IGLV2-8, MIR650, AC245028.2, IGLV3-7, IGLV3-6, IGLV2-5, IGLV3-4, IGLV4-3, IGLV3-2, IGLV3-1, MIR5571, IGLL5, IGLJ1, IGLC1, IGLJ2, IGLC2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 34 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,601,004–7,601,267, 1 gene, copy number 19: AC134684.1.
- chr8:7,715,443–7,749,044, 5 genes, copy number 33: FAM90A14P, FAM90A18P, FAM90A16P, FAM90A8P, FAM90A17P.
- chr8:12,310,962–12,318,316, 1 gene, copy number 11: DEFB130A.
- chr8:12,341,426–12,359,391, 2 genes, copy number 11: DEFB108E, ZNF705CP.
- chr14:18,333,726–18,419,273, 4 genes, copy number 9: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr15:21,927,657–21,946,641, 1 gene, copy number 14: NF1P2.
- chr15:21,980,277–21,981,245, 1 gene, copy number 15: OR11J6P.
- chr16:32,475,051–32,478,250, 1 gene, copy number 13: ABCD1P3.
- chr16:32,715,931–32,788,944, 8 genes, copy number 25: AC138907.6, ABHD17AP7, AC138907.2, AC138907.4, HERC2P5, AC138907.8, AC138907.9, AC138907.10.
- chr17:46,274,784–46,361,797, 3 genes, copy number 10: ARL17B, LRRC37A, RN7SL656P.
- chr21:44,133,610–44,210,114, 1 gene, copy number 16 (within-gene range 4–16): GATD3A.
- chr22:18,361,820–18,512,187, 6 genes, copy number 12–19: FAM230J, AC011718.1, PPP1R26P3, FAM230A, AC023490.2, FAM247B.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
